Somatic mutation profile of tumor specimen C3N-00323-02 (aliquot CPT0010610006) from CPTAC case C3N-00323, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.4 years (28,627 days).
Specimen C3N-00323-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49fbe6fa-d693-48a9-832e-2ba80cc8763a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00323-31 (Blood Derived Normal), aliquot CPT0010760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3df5ea-4031-43b5-afae-3445b0b27251

The open-access MAF lists 70 somatic variants for this specimen: 44 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 23, Intron 2, Frame Shift Del 2, Splice Region 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS5 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200886341; called by muse, mutect2, varscan2
- BDKRB2 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs962382149, COSV100021337, COSV60013916; called by muse, mutect2, varscan2
- CARMIL3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.885); catalogued as rs763509676; called by muse, mutect2
- CIDEB | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs146066890; called by muse, varscan2
- COG6 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs775668471; called by muse, mutect2, varscan2
- CSH2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 92/845 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61080493; called by muse, mutect2, varscan2
- KCNA4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1219757636; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MRGPRX3 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs149836029, COSV66934013; called by muse, mutect2, varscan2
- MUC12 | c.2222C>A p.A741D (on ENST00000379442; = p.A598D on NM_001164462.1) | Missense Mutation (SNP) | VAF 54/676 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs557849554; called by muse, mutect2
- OR10G3 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs536842323, COSV57810985; called by muse, mutect2, varscan2
- PRAMEF19 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.476); catalogued as rs1274389350; called by muse, mutect2, varscan2
- PTEN | c.773del p.F258Sfs*8 | Frame Shift Del (DEL) | VAF 121/309 reads (39%) | catalogued as CD1412159; called by mutect2, pindel, varscan2
- RSRC1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs372306685; called by muse, mutect2
- SLC9A6 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV65788410; called by muse, mutect2, varscan2
- TRIM39 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs951661055; called by muse, mutect2, varscan2
- ZDHHC22 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1426907360; called by muse, mutect2, varscan2
- ZNF267 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.139); catalogued as COSV56254325; called by muse, mutect2, varscan2
- ABCA8 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACO1 | c.1089G>C p.L363F | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ACSM4 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ACVR1B | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRF1 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.14); called by muse, mutect2
- ART4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- C9orf78 | c.419_422del p.K140Mfs*30 | Frame Shift Del (DEL) | VAF 62/209 reads (30%) | called by mutect2, pindel, varscan2
- CFAP20 | c.465+6del | Splice Region (DEL) | VAF 76/310 reads (25%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.12877C>T p.R4293C | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IRX4 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 34/403 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- NCOR2 | c.5127G>A p.M1709I | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NKAIN4 | c.471G>A p.A157= | Splice Region (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- PHF14 | c.885A>C p.Q295H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- PTP4A2 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- SF3A2 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC10A3 | c.893T>G p.F298C | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SLC26A1 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC30A7 | c.160_168del p.L54_G56del | In Frame Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- TMEM170A | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC45A | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2
- ZNF329 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF717 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- ZNF74 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA12 | c.4416T>A p.R1472= (on ENST00000272895 / NM_173076.3; = p.R1154= on NM_015657.3) | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- ASH1L | c.6090G>A p.A2030= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs748862329, COSV100853502; called by muse, mutect2, varscan2
- BHMT2 | c.291C>T p.L97= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs768662220, COSV54872107; called by muse, mutect2, varscan2
- C5orf38 | c.72G>A p.L24= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as rs1409210839; called by muse, mutect2, varscan2
- CASR | c.2433G>A p.T811= (on ENST00000490131; = p.T888= on NM_000388.4) | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs751165754, COSV56140224; called by muse, mutect2, varscan2
- CCDC166 | c.285C>T p.D95= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV101545841; called by muse, mutect2
- CFHR1 | c.795G>A p.P265= | Silent (SNP) | VAF 30/362 reads (8%) | catalogued as rs766719031, COSV57628147; called by muse, mutect2
- CNTNAP3 | c.1914C>T p.P638= | Silent (SNP) | VAF 65/247 reads (26%) | catalogued as rs1182552345; called by muse, mutect2, varscan2
- CSN2 | c.30G>T p.V10= | Silent (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- CYP7B1 | c.570G>A p.E190= | Silent (SNP) | VAF 28/269 reads (10%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.1128C>T p.L376= | Silent (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- G6PC2 | c.945C>T p.H315= | Silent (SNP) | VAF 39/286 reads (14%) | catalogued as rs370470317; called by muse, mutect2, varscan2
- GANC | c.864G>A p.S288= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs369762885; called by muse, mutect2, varscan2
- HDX | c.357G>A p.R119= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV99947220; called by muse, mutect2, varscan2
- IBSP | c.768C>T p.T256= | Silent (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- KIF3C | c.681C>T p.S227= | Silent (SNP) | VAF 36/221 reads (16%) | catalogued as rs764523801; called by muse, mutect2, varscan2
- LNX1 | c.1017C>T p.Y339= (on ENST00000263925 / NM_001126328.3; = p.Y243= on NM_032622.2) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs766245676; called by muse, mutect2, varscan2
- PCDHGB4 | c.1560C>T p.H520= | Silent (SNP) | VAF 83/461 reads (18%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6678G>A p.E2226= | Silent (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- PRR23A | c.126G>A p.A42= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- RBM4B | c.729C>T p.Y243= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as rs764283037; called by muse, mutect2, varscan2
- SIGLEC8 | c.192C>A p.G64= | Silent (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- ZNF574 | c.2091C>T p.V697= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- MRPS14 | c.45+67C>T | Intron (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- NCF4 | c.758+9C>T | Intron (SNP) | VAF 63/296 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.*165G>T | 3'UTR (SNP) | VAF 10/146 reads (7%) | catalogued as COSV54727845; called by muse, mutect2
